Somatic mutation profile of tumor specimen TCGA-B0-5700-01A (aliquot TCGA-B0-5700-01A-11D-1534-10) from TCGA case TCGA-B0-5700, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 77.2 years (28,184 days).
Specimen TCGA-B0-5700-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4b69f1e-5ee4-4cf5-8dcc-c34340d0561c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5700-11A (Solid Tissue Normal), aliquot TCGA-B0-5700-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81b3dffd-4933-499a-922f-bbd445d835c1

The open-access MAF lists 67 somatic variants for this specimen: 56 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 8, Frame Shift Del 6, Splice Site 4, In Frame Del 2, 3'UTR 2, Frame Shift Ins 2, Nonsense Mutation 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 54/129 reads (42%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by muse, mutect2, varscan2
- ADRA2A | c.1380C>G p.D460E | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV99701611; called by muse, mutect2, varscan2
- ANK3 | c.5543C>T p.S1848L | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as COSV55089018; called by muse, mutect2, varscan2
- ANTXR1 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 163/549 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs370351341, COSV58009335; called by muse, mutect2, varscan2
- ARHGAP45 | c.2852C>G p.S951C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99297515; called by muse, mutect2, varscan2
- BIRC6 | c.10098G>T p.L3366F | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV70197658; called by muse, mutect2, varscan2
- CWF19L2 | c.573C>G p.S191= | Splice Region (SNP) | VAF 36/151 reads (24%) | catalogued as COSV99978866; called by muse, mutect2, varscan2
- DDHD2 | c.1691A>C p.H564P | Missense Mutation (SNP) | VAF 102/425 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101240616; called by muse, mutect2, varscan2
- DENND2C | c.1319C>A p.T440K (on ENST00000393274 / NM_001256404.2; = p.T383K on NM_198459.4) | Missense Mutation (SNP) | VAF 76/296 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV101283917; called by mutect2, varscan2
- DISC1 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV99697642; called by muse, mutect2, varscan2
- DPP10 | c.1221+1G>A p.X407_splice | Splice Site (SNP) | VAF 35/435 reads (8%) | catalogued as COSV59686879; called by muse, mutect2
- FAT1 | c.5660C>A p.S1887Y | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV101499301; called by muse, mutect2, varscan2
- FLII | c.2537A>C p.Y846S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100375303; called by muse, mutect2, varscan2
- FLT3 | c.266T>G p.I89S | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99608445; called by muse, mutect2
- FRAS1 | c.5969A>G p.D1990G | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as COSV99351003; called by muse, mutect2, varscan2
- IFNA13 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.063); catalogued as COSV101489480; called by muse, mutect2, varscan2
- IPPK | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99845565; called by muse, mutect2, varscan2
- KNTC1 | c.2879T>C p.V960A | Missense Mutation (SNP) | VAF 64/282 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as COSV100338228; called by muse, mutect2, varscan2
- KYNU | c.190A>G p.K64E | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1322808333, COSV99933142; called by muse, mutect2, varscan2
- L2HGDH | c.1198G>A p.G400S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs747054983, COSV99910240; called by muse, mutect2
- L2HGDH | c.1197-1G>A p.X399_splice | Splice Site (SNP) | VAF 24/93 reads (26%) | catalogued as COSV99910241; called by muse, mutect2
- MCM10 | c.536A>T p.D179V (on ENST00000484800 / NM_182751.3; = p.D178V on NM_018518.5) | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV101098076; called by muse, mutect2, varscan2
- MEGF10 | c.3328C>A p.H1110N | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99174877; called by muse, varscan2
- MYO10 | c.5059T>A p.S1687T | Missense Mutation (SNP) | VAF 63/310 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99945195; called by muse, mutect2, varscan2
- NEDD4 | c.3791A>T p.N1264I (on ENST00000508342 / NM_001284338.1; = p.N845I on NM_006154.4) | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100163645; called by muse, mutect2, varscan2
- NPIPB15 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as rs369741448, COSV70436870; called by muse, mutect2, varscan2
- NUP88 | c.241G>C p.V81L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.11); catalogued as COSV99851609; called by muse, mutect2, varscan2
- OR8D1 | c.417G>T p.W139C | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV63441737; called by muse, mutect2, varscan2
- PEAR1 | c.2450A>G p.Y817C | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99441244; called by muse, mutect2, varscan2
- PRKCH | c.1498A>T p.M500L | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV100273208; called by muse, mutect2, varscan2
- PRKRA | c.266A>T p.H89L | Missense Mutation (SNP) | VAF 81/259 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV100359544; called by muse, mutect2, varscan2
- PTPRG | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99874498; called by muse, mutect2, varscan2
- PTPRM | c.373C>A p.L125M | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100156767; called by muse, mutect2, varscan2
- RABEPK | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as rs1354724729, COSV52336133; called by muse, mutect2, varscan2
- RABEPK | c.1022A>G p.E341G | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99413355; called by muse, mutect2, varscan2
- RC3H2 | c.2623A>C p.K875Q | Missense Mutation (SNP) | VAF 117/365 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100605504; called by muse, mutect2, varscan2
- ROS1 | c.4534G>A p.D1512N | Missense Mutation (SNP) | VAF 91/303 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV100876981; called by muse, mutect2, varscan2
- SNRNP200 | c.5957T>C p.M1986T | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs1448076768, COSV99720380; called by muse, mutect2, varscan2
- TEAD4 | c.287A>T p.K96M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100622009; called by muse, mutect2, varscan2
- TMEM209 | c.77G>T p.R26M | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.853); catalogued as COSV99927694; called by muse, mutect2
- TNFRSF1A | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99164183; called by muse, mutect2, varscan2
- UBA6 | c.1780A>G p.M594V | Missense Mutation (SNP) | VAF 56/287 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as rs751280009, COSV100451666; called by muse, mutect2, varscan2
- USP3 | c.1397+2T>A p.X466_splice | Splice Site (SNP) | VAF 39/163 reads (24%) | catalogued as COSV99165688; called by muse, mutect2, varscan2
- ZFYVE27 | c.197+2T>C p.X66_splice | Splice Site (SNP) | VAF 68/240 reads (28%) | catalogued as COSV100519259; called by muse, mutect2, varscan2
- ZNF562 | c.1169A>C p.H390P (on ENST00000453372 / NM_001130032.2; = p.H318P on NM_017656.4) | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99530659; called by muse, mutect2, varscan2
- ZNF638 | c.5771C>G p.P1924R | Missense Mutation (SNP) | VAF 143/485 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100038577; called by muse, mutect2, varscan2
- ABO | c.247del p.D83Mfs*4 | Frame Shift Del (DEL) | VAF 29/91 reads (32%) | called by mutect2, pindel*, varscan2
- ADAMTS12 | c.4029_4030del p.Q1343Hfs*4 | Frame Shift Del (DEL) | VAF 67/161 reads (42%) | called by mutect2, pindel, varscan2
- BTG4 | c.262_272del p.L88Dfs*9 | Frame Shift Del (DEL) | VAF 132/501 reads (26%) | called by mutect2, pindel, varscan2
- CATSPER3 | c.123del p.F42Lfs*2 | Frame Shift Del (DEL) | VAF 60/338 reads (18%) | called by mutect2, pindel, varscan2
- GAS8 | c.1104del p.E368Dfs*7 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | called by mutect2, pindel, varscan2
- MACF1 | c.10628_10636del p.A3543_L3545del | In Frame Del (DEL) | VAF 36/170 reads (21%) | called by mutect2, pindel, varscan2
- NAPEPLD | c.543_545del p.L182del | In Frame Del (DEL) | VAF 48/167 reads (29%) | called by mutect2, pindel, varscan2
- PEG10 | c.34del p.E12Rfs*5 (on ENST00000482108 / NM_001040152.2; = p.E46Rfs*5 on NM_015068.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | called by pindel, varscan2
- R3HCC1L | c.1241dup p.F415Vfs*15 | Frame Shift Ins (INS) | VAF 71/256 reads (28%) | called by mutect2, pindel, varscan2
- ZBTB24 | c.594dup p.V199Cfs*3 | Frame Shift Ins (INS) | VAF 57/237 reads (24%) | called by mutect2, pindel, varscan2
- AURKAIP1 | c.24C>T p.S8= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1386400331, COSV100408653; called by muse, mutect2
- CSF1R | c.2058C>T p.S686= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as rs1177452969, COSV99641647; called by muse, mutect2, varscan2
- CXCR6 | c.1008C>A p.A336= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV99945564; called by muse, mutect2, varscan2
- EFNA5 | c.600C>T p.R200= | Silent (SNP) | VAF 86/313 reads (27%) | catalogued as rs142641037; called by muse, mutect2, varscan2
- FCRL6 | c.594C>T p.V198= | Silent (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- SLC7A9 | c.774C>A p.I258= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV50091389, COSV99195264; called by muse, mutect2, varscan2
- TMC7 | c.1233T>G p.S411= | Silent (SNP) | VAF 95/311 reads (31%) | catalogued as COSV100432452; called by muse, mutect2, varscan2
- ZNF700 | c.210G>A p.Q70= | Silent (SNP) | VAF 132/481 reads (27%) | catalogued as COSV99583468; called by muse, mutect2, varscan2
- DCAF6 | c.*4dup | 3'UTR (INS) | VAF 86/358 reads (24%) | called by pindel, varscan2
- SSPOP | n.9327C>A | RNA (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100947290; called by muse, mutect2, varscan2
- ZNF611 | c.*2A>G | 3'UTR (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100160236; called by muse, mutect2, varscan2
